Somatic mutation profile of tumor specimen MP2PRT-PAWAVL-TMP1-A (aliquot MP2PRT-PAWAVL-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAWAVL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.2 years (2,996 days).
Specimen MP2PRT-PAWAVL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 231790d8-b2fb-43f7-a7ff-366f94f8bf9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWAVL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWAVL-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96e3ca2e-b41d-431a-b5f5-f59d17703264

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 13, Silent 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAP31 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1420709522; called by muse, mutect2, varscan2
- LRRC52 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 82/419 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs781381076, COSV54232318; called by muse, mutect2, varscan2
- SH2B1 | c.2149G>C p.A717P | Missense Mutation (SNP) | VAF 76/822 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs775937151; called by muse, mutect2
- COL22A1 | c.3505A>T p.S1169C | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- CPHXL | c.578T>G p.L193R | Missense Mutation (SNP) | VAF 21/334 reads (6%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- EHBP1 | c.1243A>G p.N415D | Missense Mutation (SNP) | VAF 19/358 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.034); called by muse, mutect2
- FSIP2 | c.2968C>A p.P990T | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); called by muse, mutect2
- FUT4 | c.422G>C p.R141P | Missense Mutation (SNP) | VAF 34/935 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.805); called by muse, mutect2
- LRP1B | c.13586G>A p.S4529N | Missense Mutation (SNP) | VAF 19/387 reads (5%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.827); called by muse, mutect2
- MDN1 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MXD4 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PON2 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 78/414 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ZFPM2 | c.1964C>A p.T655N | Missense Mutation (SNP) | VAF 34/525 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- AVPR1B | c.216C>T p.F72= | Silent (SNP) | VAF 105/553 reads (19%) | catalogued as rs782749281, COSV65637761; called by muse, mutect2, varscan2
- DNASE1L2 | c.795G>A p.S265= | Silent (SNP) | VAF 36/510 reads (7%) | called by muse, mutect2
- ORM2 | c.357G>A p.L119= | Silent (SNP) | VAF 75/291 reads (26%) | called by muse, varscan2
- SLC23A2 | c.1116G>T p.L372= | Silent (SNP) | VAF 22/246 reads (9%) | called by muse, mutect2
- TECTA | c.5598G>A p.T1866= | Silent (SNP) | VAF 68/222 reads (31%) | catalogued as rs146930070, COSV50808919; called by muse, mutect2
- TFEC | c.750G>A p.Q250= | Silent (SNP) | VAF 98/437 reads (22%) | catalogued as rs1179400346; called by muse, mutect2, varscan2
- ZMYND8 | c.1668C>T p.F556= (on ENST00000311275 / NM_001363741.2; = p.F576= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/371 reads (17%) | called by muse, mutect2, varscan2
